Surgical pathology report (de-identified scan), TCGA case TCGA-B4-5377, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Cureline, specimen TCGA-B4-5377-01A (Primary Tumor).

[page 1 of 3]
Index	Cureline Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement
1					Female		Kidney cancer	
					Female		Kidney cancer	

[page 2 of 3]
Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit
Kidney, right	Primary	Tumor	Tissue	OCT	block	1	n/a	n/a
Blood	n/a	Normal	Blood	frozen	tube	1	n/a	n/a

[page 3 of 3]
Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
surgery	Clear cell carcinoma	3	3	0	1	none	n/a	72
blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

Source: NCI Genomic Data Commons file 639d5dcf-c23d-492c-a848-0e3509f19c48 (TCGA-B4-5377.61641668-8108-4B67-AD46-A9A30858F5C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).